Somatic mutation profile of tumor specimen TCGA-FF-8061-01A (aliquot TCGA-FF-8061-01A-11D-2210-10) from TCGA case TCGA-FF-8061, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Small intestine, NOS; Age at diagnosis: 42.0 years (15,358 days).
Specimen TCGA-FF-8061-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d2466fa9-f5e1-4f88-be53-15ff2cef5a9d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FF-8061-10A (Blood Derived Normal), aliquot TCGA-FF-8061-10A-01D-2210-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fdabcd76-29f9-45fa-a623-d2356ba8cbd1

The open-access MAF lists 138 somatic variants for this specimen: 109 protein-altering or splice-affecting, 19 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 98, Silent 19, Nonsense Mutation 6, Intron 5, 3'UTR 3, Splice Region 2, Frame Shift Del 2, 5'UTR 1, 5'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B2M | c.35T>C p.L12P | Missense Mutation (SNP) | VAF 69/91 reads (76%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62562913, COSV62563197; called by muse, mutect2, varscan2
- PIM1 | c.4C>T p.L2F | Missense Mutation (SNP) | VAF 9/28 reads (32%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.942); catalogued as rs774518045, COSV65164509, COSV65165235; called by muse, varscan2
- ACTG1 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 94/270 reads (35%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs375334153, COSV100111847; called by muse, varscan2
- ADAMTSL5 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.594); catalogued as rs550092054; called by muse, mutect2, varscan2
- ADGRL1 | c.4333C>T p.R1445C (on ENST00000340736 / NM_001008701.3; = p.R1440C on NM_014921.5) | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs375528213; called by muse, mutect2, varscan2
- ATP10A | c.1001G>A p.R334Q | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0.022); catalogued as rs144743073; called by muse, mutect2, varscan2
- BTG1 | c.8C>G p.P3R | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.054); catalogued as COSV55460582; called by muse, mutect2, varscan2
- C3 | c.509C>T p.P170L | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771707355, COSV99835756; called by muse, mutect2, varscan2
- CACNA1C | c.1671C>T p.D557= | Splice Region (SNP) | VAF 15/35 reads (43%) | catalogued as rs751998767; called by muse, mutect2, varscan2
- CARD11 | c.1079T>C p.M360T | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as COSV67796896, COSV67797170; called by muse, mutect2, varscan2
- CDRT1 | c.563A>C p.K188T | Missense Mutation (SNP) | VAF 15/193 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV99887799; called by muse, mutect2
- CLPSL1 | c.167A>G p.N56S | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.57); PolyPhen benign (0.01); catalogued as rs769362762; called by muse, mutect2, varscan2
- COL21A1 | c.2864C>T p.P955L | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs759100067; called by muse, mutect2, varscan2
- CRMP1 | c.46C>T p.R16* | Nonsense Mutation (SNP) | VAF 23/75 reads (31%) | catalogued as rs769736612; called by muse, mutect2, varscan2
- DEK | c.750A>C p.E250D | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.593); catalogued as COSV55238733; called by muse, mutect2, varscan2
- DNAH6 | c.1744A>G p.S582G | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV52887588; called by muse, mutect2, varscan2
- DPYD | c.2789A>G p.Q930R | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs568169006; called by muse, mutect2, varscan2
- GDPD4 | c.32G>A p.S11N | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759673381; called by muse, mutect2, varscan2
- GPX5 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 85/107 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs138279209; called by muse, mutect2, varscan2
- GRID2 | c.1616G>A p.R539H | Missense Mutation (SNP) | VAF 58/170 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs772260836, COSV56271597; called by muse, mutect2, varscan2
- HSD17B7 | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0.011); catalogued as rs1403586392, COSV54419287; called by muse, mutect2, varscan2
- IGHV2-70 | c.166A>T p.S56C | Missense Mutation (SNP) | VAF 128/160 reads (80%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.634); catalogued as rs759335337; called by muse, varscan2
- IGHV3-72 | c.208A>G p.T70A | Missense Mutation (SNP) | VAF 46/148 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as rs376097218; called by muse, mutect2, varscan2
- IGLL5 | c.113T>G p.L38R | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.031); catalogued as rs777043119; called by muse, varscan2
- LLGL2 | c.116G>A p.G39D | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as rs1462940504; called by muse, mutect2, varscan2
- LYN | c.1097G>A p.R366Q | Missense Mutation (SNP) | VAF 58/167 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101319614; called by muse, mutect2, varscan2
- MYO18B | c.6949G>A p.A2317T | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs187337528; called by muse, mutect2, varscan2
- MYOF | c.4916T>C p.I1639T | Missense Mutation (SNP) | VAF 57/131 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as rs773089825; called by muse, mutect2, varscan2
- NAGA | c.289C>A p.R97S | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs140775168; called by muse, mutect2, varscan2
- NID2 | c.1511A>G p.Y504C | Missense Mutation (SNP) | VAF 64/176 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1328018969; called by muse, varscan2
- NPY2R | c.772C>T p.H258Y | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.186); catalogued as rs1435941045; called by muse, mutect2, varscan2
- NUP210 | c.3508G>A p.V1170M | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); catalogued as rs772578384, COSV54416725; called by muse, mutect2, varscan2
- P2RY8 | c.867C>A p.D289E | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67176838; called by muse, mutect2, varscan2
- PCDHA10 | c.1202A>G p.K401R | Missense Mutation (SNP) | VAF 73/172 reads (42%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.03); catalogued as COSV56510183; called by muse, mutect2, varscan2
- PCLO | c.12196T>C p.F4066L | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as rs1458366772; called by muse, mutect2, varscan2
- PLXNA2 | c.3926G>A p.R1309H | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as rs572241200, COSV65445667; called by muse, mutect2, varscan2
- PRKACA | c.811C>T p.R271W | Missense Mutation (SNP) | VAF 62/151 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1179462944; called by muse, mutect2, varscan2
- PRKCB | c.1279G>A p.D427N | Missense Mutation (SNP) | VAF 55/154 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV100333233, COSV57764210; called by muse, mutect2, varscan2
- RIMBP2 | c.2861C>T p.T954M | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs764908696, COSV55477244; called by muse, mutect2, varscan2
- RNF123 | c.3551G>A p.R1184H | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs769239848, COSV57540711; called by muse, mutect2, varscan2
- RNF133 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0.434); catalogued as rs759225467, COSV57376938; called by muse, mutect2, varscan2
- SYNE1 | c.10450G>A p.V3484I (on ENST00000367255 / NM_182961.4; = p.V3491I on NM_033071.3) | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as rs550088683, COSV55081595; called by muse, mutect2, varscan2
- TCL1A | c.113C>T p.T38I | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs201228671, COSV68085105, COSV68085114, COSV68085683; called by muse, mutect2, varscan2
- TET2 | c.4312A>T p.K1438* | Nonsense Mutation (SNP) | VAF 101/120 reads (84%) | catalogued as COSV54415797; called by muse, mutect2, varscan2
- TLN2 | c.3173C>T p.T1058M | Missense Mutation (SNP) | VAF 30/35 reads (86%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as rs767177524; called by muse, mutect2, varscan2
- TMTC4 | c.1246C>T p.L416F (on ENST00000376234 / NM_001350577.2; = p.L435F on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100168910; called by muse, mutect2, varscan2
- VAX2 | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 60/172 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as rs782299811, COSV52266213; called by muse, mutect2, varscan2
- ZDBF2 | c.5617A>G p.K1873E | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746951501, COSV65623567; called by muse, mutect2, varscan2
- ZFHX3 | c.5815G>A p.D1939N | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.815); catalogued as COSV51713635; called by muse, mutect2, varscan2
- ADAMTS5 | c.1201G>A p.G401S | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADO | c.528C>G p.Y176* | Nonsense Mutation (SNP) | VAF 4/21 reads (19%) | called by muse, mutect2
- AKAP9 | c.876A>C p.E292D | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.742); called by muse, varscan2
- AKAP9 | c.930+3A>C | Splice Region (SNP) | VAF 6/16 reads (38%) | called by muse, varscan2
- ANO8 | c.2732A>G p.Q911R | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- ARHGAP11A | c.1331A>T p.N444I | Missense Mutation (SNP) | VAF 45/220 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- ATAD5 | c.5352_5356del p.L1785Cfs*3 | Frame Shift Del (DEL) | VAF 14/47 reads (30%) | called by pindel, varscan2
- BTG2 | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CACNA1C | c.6068T>C p.F2023S (on ENST00000399634 / NM_001167625.1; = p.F1952S on NM_000719.7) | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- CADM2 | c.362T>G p.L121R (on ENST00000407528 / NM_001167674.2; = p.L123R on NM_153184.4) | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CD163L1 | c.1153A>G p.R385G | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- CDH13 | c.1719A>G p.I573M | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- CEP126 | c.2277A>C p.K759N | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- CIT | c.305T>C p.L102P | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CPLX3 | c.9C>A p.F3L | Missense Mutation (SNP) | VAF 42/51 reads (82%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- DHRS12 | c.681G>A p.M227I (on ENST00000444610 / NM_001377930.1; = p.M178I on NM_024705.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- DPF1 | c.956A>G p.N319S | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.895); called by muse, mutect2
- ETV5 | c.583C>T p.R195* | Nonsense Mutation (SNP) | VAF 70/159 reads (44%) | called by muse, mutect2, varscan2
- GP2 | c.1180T>G p.F394V (on ENST00000381362 / NM_001007240.3; = p.F391V on NM_001502.4) | Missense Mutation (SNP) | VAF 36/175 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- H1-5 | c.317G>C p.G106A | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- H2BC21 | c.361A>G p.K121E | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- IGHA2 | c.380G>A p.G127D | Missense Mutation (SNP) | VAF 80/187 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.618); called by muse, mutect2, varscan2
- IGHG1 | c.233C>T p.T78I | Missense Mutation (SNP) | VAF 88/129 reads (68%) | SIFT deleterious (0.02); PolyPhen benign (0.346); called by muse, varscan2
- IGHV4-31 | c.153_161del p.G52_S54del | In Frame Del (DEL) | VAF 18/140 reads (13%) | called by mutect2, pindel
- IGLV4-3 | c.197T>A p.I66K | Missense Mutation (SNP) | VAF 52/113 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- IWS1 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 51/160 reads (32%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KANK1 | c.2954A>G p.K985R | Missense Mutation (SNP) | VAF 66/142 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MGAT5 | c.997G>A p.G333R | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYO1D | c.2712G>T p.L904F | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.026); called by muse, varscan2
- NBEA | c.5387A>G p.K1796R | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- NFKBIA | c.811C>T p.Q271* | Nonsense Mutation (SNP) | VAF 42/166 reads (25%) | called by muse, mutect2, varscan2
- NFKBIE | c.938T>A p.L313Q (on ENST00000275015; = p.L174Q on NM_004556.3) | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- NMUR1 | c.1176G>A p.M392I | Missense Mutation (SNP) | VAF 56/143 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- NOSIP | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NPAS4 | c.1076C>A p.T359N | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- OBI1 | c.194G>C p.C65S | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- P2RY10 | c.796del p.Y266Tfs*4 | Frame Shift Del (DEL) | VAF 26/40 reads (65%) | called by mutect2, pindel, varscan2
- P2RY8 | c.235C>A p.Q79K | Missense Mutation (SNP) | VAF 97/238 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PARD6G | c.227A>G p.N76S | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDH17 | c.920G>A p.G307D | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PDGFC | c.795A>T p.R265S | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- PDS5B | c.2539G>A p.G847R | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- PFDN2 | c.206A>C p.K69T | Missense Mutation (SNP) | VAF 9/124 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- PGM3 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- PLCH1 | c.2538A>C p.E846D (on ENST00000340059 / NM_001130960.2; = p.E858D on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); called by muse, mutect2
- PPP1R36 | c.790G>A p.G264R | Missense Mutation (SNP) | VAF 66/140 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PSG4 | c.80T>G p.F27C | Missense Mutation (SNP) | VAF 70/180 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- RFX6 | c.2110C>T p.Q704* | Nonsense Mutation (SNP) | VAF 53/109 reads (49%) | called by muse, mutect2, varscan2
- RPGRIP1L | c.209A>C p.K70T | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- SEPTIN7 | c.1076A>G p.Q359R | Missense Mutation (SNP) | VAF 82/239 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SERPINB10 | c.716T>G p.L239R | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- SH3YL1 | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC17A9 | c.769A>G p.I257V | Missense Mutation (SNP) | VAF 55/115 reads (48%) | SIFT tolerated (0.67); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SNRPD2 | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 75/193 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- STPG2 | c.928T>G p.Y310D | Missense Mutation (SNP) | VAF 62/162 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SWAP70 | c.94C>T p.L32F | Missense Mutation (SNP) | VAF 83/190 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); called by muse, mutect2, varscan2
- TTK | c.1715T>A p.I572K | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UHRF2 | c.68C>G p.A23G | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.369); called by muse, mutect2, varscan2
- WSCD2 | c.958G>A p.V320M | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZBED2 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 71/178 reads (40%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARMCX5 | c.1254G>A p.G418= | Silent (SNP) | VAF 10/87 reads (11%) | catalogued as COSV55766625; called by muse, mutect2, varscan2
- AUP1 | c.177C>T p.S59= | Silent (SNP) | VAF 53/72 reads (74%) | catalogued as rs750726884; called by muse, mutect2, varscan2
- CFH | c.666T>C p.S222= | Silent (SNP) | VAF 27/83 reads (33%) | called by muse, mutect2, varscan2
- CLVS1 | c.510C>T p.I170= | Silent (SNP) | VAF 30/85 reads (35%) | catalogued as rs746041983, COSV57971952; called by muse, mutect2, varscan2
- COL16A1 | c.2361G>A p.R787= | Silent (SNP) | VAF 28/67 reads (42%) | called by muse, mutect2, varscan2
- COL3A1 | c.171A>G p.S57= | Silent (SNP) | VAF 41/115 reads (36%) | called by muse, mutect2, varscan2
- DUSP2 | c.723C>G p.G241= | Silent (SNP) | VAF 24/56 reads (43%) | called by muse, mutect2, varscan2
- FSD1L | c.1374T>C p.D458= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as rs1025292547; called by muse, mutect2, varscan2
- IGLL5 | c.46C>T p.L16= | Silent (SNP) | VAF 58/148 reads (39%) | catalogued as rs564743210, COSV73249743, COSV73250317, COSV73251309; called by muse, varscan2
- IGLL5 | c.78G>A p.L26= | Silent (SNP) | VAF 56/134 reads (42%) | catalogued as rs551962377, COSV73250938; called by muse, varscan2
- IGLL5 | c.114G>C p.L38= | Silent (SNP) | VAF 42/117 reads (36%) | catalogued as rs556230331, COSV73249618, COSV73250730; called by muse, varscan2
- IGLV3-25 | c.207C>T p.D69= | Silent (SNP) | VAF 49/151 reads (32%) | catalogued as rs537094286; called by muse, mutect2, varscan2
- ITSN1 | c.2826C>T p.V942= | Silent (SNP) | VAF 53/128 reads (41%) | called by muse, mutect2, varscan2
- MKNK2 | c.873C>T p.G291= | Silent (SNP) | VAF 5/39 reads (13%) | called by muse, mutect2
- NEB | c.10758G>A p.K3586= | Silent (SNP) | VAF 88/223 reads (39%) | called by muse, mutect2, varscan2
- PITPNM3 | c.2733C>T p.H911= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as rs1474061486; called by muse, mutect2, varscan2
- RYR1 | c.2502G>A p.R834= | Silent (SNP) | VAF 31/61 reads (51%) | called by muse, mutect2, varscan2
- SGK1 | c.480G>T p.V160= | Silent (SNP) | VAF 26/195 reads (13%) | called by muse, mutect2, varscan2
- ZBTB8B | c.1122C>T p.C374= | Silent (SNP) | VAF 34/104 reads (33%) | catalogued as rs774509172; called by muse, mutect2, varscan2
- CFAP410 | c.97-14T>A | Intron (SNP) | VAF 49/105 reads (47%) | called by muse, mutect2, varscan2
- DPAGT1 | chr11:119102357 A>G | 5'Flank (SNP) | VAF 15/43 reads (35%) | called by muse, mutect2, varscan2
- FAHD1 | c.*730C>A | 3'UTR (SNP) | VAF 60/146 reads (41%) | catalogued as COSV101232556; called by muse, mutect2, varscan2
- H2BC17 | c.*1G>A | 3'UTR (SNP) | VAF 39/166 reads (23%) | catalogued as rs755407671; called by muse, mutect2, varscan2
- HSD11B1L | c.73+14G>A | Intron (SNP) | VAF 33/89 reads (37%) | catalogued as rs762846306; called by muse, mutect2, varscan2
- KCNQ2 | c.1118+46del | Intron (DEL) | VAF 4/28 reads (14%) | catalogued as rs1329161776; called by pindel, varscan2
- MYBL1 | c.-17T>A | 5'UTR (SNP) | VAF 44/96 reads (46%) | catalogued as COSV101576593; called by muse, varscan2
- NRXN1 | c.1320+115A>C | Intron (SNP) | VAF 31/109 reads (28%) | called by muse, mutect2, varscan2
- PI4KA | c.*12T>G | 3'UTR (SNP) | VAF 100/237 reads (42%) | catalogued as COSV99748092; called by muse, mutect2, varscan2
- SGK1 | c.77-31C>T | Intron (SNP) | VAF 28/51 reads (55%) | catalogued as COSV52804810, COSV52804994; called by muse, mutect2, varscan2
